Somatic mutation profile of tumor specimen 0DR53D from CCDI case PBCFTR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Central neurocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 19.0 years (6,933 days).
Specimen 0DR53D: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 381f2751-c94b-4641-9d54-a72c9c5cfea0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DR537 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/651a5d73-00c4-46c2-b6d6-6ee183f40044

The open-access MAF lists 13 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 3, Nonsense Mutation 2, Intron 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BMP7 | c.1064C>T p.A355V | Missense Mutation (SNP) | VAF 303/655 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as COSV67782611; called by muse, mutect2, varscan2
- CACNA1H | c.3310C>T p.R1104W | Missense Mutation (SNP) | VAF 16/404 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs1198273560; called by muse, mutect2
- EGR3 | c.374C>T p.S125F | Missense Mutation (SNP) | VAF 13/274 reads (5%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.961); catalogued as COSV100416225; called by muse, mutect2
- WDFY3 | c.9496C>T p.R3166* | Nonsense Mutation (SNP) | VAF 40/1172 reads (3%) | catalogued as rs866536893; called by muse, mutect2
- ZSCAN10 | c.1553C>A p.T518K (on ENST00000252463; = p.T573K on NM_032805.3) | Missense Mutation (SNP) | VAF 14/312 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV52970937; called by muse, mutect2
- DST | c.4315A>T p.K1439* (on ENST00000361203 / NM_001374722.1; = p.K1113* on NM_015548.5) | Nonsense Mutation (SNP) | VAF 42/1016 reads (4%) | called by muse, mutect2
- TMC4 | c.56T>C p.L19P | Missense Mutation (SNP) | VAF 112/322 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.012); called by muse, mutect2
- PCSK5 | c.2292A>G p.G764= | Silent (SNP) | VAF 66/461 reads (14%) | catalogued as COSV100950397; called by muse, mutect2, varscan2
- PRR14L | c.2667C>T p.T889= | Silent (SNP) | VAF 26/648 reads (4%) | catalogued as rs902437741, COSV57884611; called by muse, mutect2
- WDFY4 | c.3282G>A p.T1094= | Silent (SNP) | VAF 324/589 reads (55%) | catalogued as rs1025102712; called by muse, mutect2, varscan2
- ALG13 | c.*49T>A | 3'UTR (SNP) | VAF 15/137 reads (11%) | called by muse, mutect2, varscan2
- BRMS1 | c.358+24C>G | Intron (SNP) | VAF 24/110 reads (22%) | called by muse, mutect2, varscan2
- ZNF596 | c.223+24C>T | Intron (SNP) | VAF 41/630 reads (7%) | called by muse, mutect2
